Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4176, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4176-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

[REDACTED] with right renal mass.

Specimens Submitted:

1: SP: Kidney, right, nephrectomy [REDACTED]

DIAGNOSIS:

1. SP: Kidney, right, nephrectomy [REDACTED]

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 4.5 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor $\leq$ 7.0 cm in greatest dimension limited to the kidney

[page 2 of 2]
[REDACTED]

[REDACTED]

[REDACTED]

Gross Description:

[REDACTED]

1) The specimen is received fresh for frozen section diagnosis, labeled, "Right kidney". It consists of a 26.0 x 12.0 x 6.5 cm nephrectomy specimen with abundant attached perinephric fat. The specimen is bivalved revealing a 10.0 x 6.0 x 5.0 cm kidney with a 4.5 x 4.5 x 3.5 cm circumscribed yellow mass within the renal cortex mid-pole and extending into the adjacent perinephric fat. Gross hemorrhage is identified. The mass does not extend into the pelvi-calyceal system. The renal vein is grossly uninvolved by tumor. The adrenal gland is not present within the specimen. The specimen is serially sectioned for lymph node identification and no lymph nodes are grossly identified. The remaining renal parenchyma is serially sectioned at 0.5 cm intervals and does not reveal any other grossly obvious lesions. TPS and photographs are taken.

Summary of Sections:

FSC -- frozen section control

MARG -- vascular and ureteral margins

NL -- representative normal

MASS -- multiple sections of mass

Summary of Sections:

Part 1: SP: Kidney, right, nephrectomy (fs) (pjm/lmg)

Block	Sect. Site	PCs
1	fsc	1
1	marg	1
6	mass	6
1	nl	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CELL CARCINOMA, CONVENTIONAL [REDACTED]
PERMANENT DIAGNOSIS: SAME
- [REDACTED]

Source: NCI Genomic Data Commons file fd2bb54c-e99a-4f0d-9eb1-1856d28e6eda (TCGA-BP-4176.104BB086-299D-4AA3-A07B-27066D1D036F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).